Somatic mutation profile of cancer-model specimen HCM-SANG-0276-C18-85A (3D Organoid; aliquot HCM-SANG-0276-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0276-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G3.
Specimen HCM-SANG-0276-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3e78d13-ebba-47e7-8486-dd0b3da26a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0276-C18-10A (Blood Derived Normal), aliquot HCM-SANG-0276-C18-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eba7b6c6-c4a7-4fa8-8b3c-c966049891d4

The open-access MAF lists 1,976 somatic variants for this specimen: 1,466 protein-altering or splice-affecting, 439 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,089, Silent 439, Frame Shift Del 225, Frame Shift Ins 67, Nonsense Mutation 58, Intron 41, 5'UTR 11, 3'UTR 11, Splice Site 10, In Frame Del 9, Splice Region 7, 3'Flank 4.

Variants (750 of 1,976; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 117/317 reads (37%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRCA2 | c.3860del p.N1287Ifs*6 | Frame Shift Del (DEL) | VAF 78/142 reads (55%) | catalogued as rs80359406; ClinVar: uncertain significance / likely benign / pathogenic; called by mutect2, varscan2
- COL6A3 | c.7660G>A p.A2554T | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786205870, CM155237, COSV55079688, COSV55087029; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- DCPS | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs138737928; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ESCO2 | c.760del p.T254Lfs*13 | Frame Shift Del (DEL) | VAF 102/206 reads (50%) | catalogued as rs80359852; ClinVar: pathogenic; called by mutect2, varscan2
- HTRA1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs113993968, CM092288, COSV100934744, COSV64563247; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 86/194 reads (44%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MC2R | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 188/382 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as rs139218324, CM116421; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 99/206 reads (48%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NOTCH3 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 33/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs28933697, CM961044, COSV54637078; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 155/320 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2165dup p.E723Gfs*5 | Frame Shift Ins (INS) | VAF 58/144 reads (40%) | catalogued as rs397507178; ClinVar: pathogenic; called by mutect2, varscan2
- SELENBP1 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 18/223 reads (8%) | catalogued as rs1553204817, COSV100923616, COSV64373565; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SLC18A2 | c.711del p.F238Sfs*48 | Frame Shift Del (DEL) | VAF 144/332 reads (43%) | catalogued as rs762879329, COSV53693545; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 51/430 reads (12%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- A2ML1 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 125/244 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.07); catalogued as COSV100229512; called by muse, mutect2, varscan2
- ABCB5 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 158/325 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV101295872; called by muse, mutect2, varscan2
- ABCB9 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 196/378 reads (52%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); catalogued as rs751721437, COSV54892022; called by muse, mutect2, varscan2
- ABCC8 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as CM133125, CM144526; called by muse, mutect2
- ABCG8 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 177/388 reads (46%) | catalogued as rs780072835, CM012310, COSV55393144; called by muse, mutect2, varscan2
- ABL1 | c.1901G>A p.G634D | Missense Mutation (SNP) | VAF 232/464 reads (50%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as rs1284103223, COSV59323776; called by muse, mutect2, varscan2
- AC006059.2 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV100045260; called by muse, mutect2
- ACCSL | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs750068165; called by muse, mutect2, varscan2
- ACKR4 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 172/348 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); catalogued as rs770290540, COSV51442366; called by muse, mutect2, varscan2
- ACVR1B | c.85del p.V29Sfs*57 | Frame Shift Del (DEL) | VAF 154/403 reads (38%) | catalogued as rs1425551425; called by pindel, varscan2
- ACVR1B | c.998A>G p.H333R | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as COSV57779763; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 212/221 reads (96%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM22 | c.991del p.S331Rfs*22 | Frame Shift Del (DEL) | VAF 114/347 reads (33%) | catalogued as rs34958294; called by mutect2, pindel, varscan2
- ADAMTS2 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 254/490 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs767211796; called by muse, mutect2, varscan2
- ADAMTS5 | c.2477C>T p.T826M | Missense Mutation (SNP) | VAF 143/300 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs150380425; called by muse, mutect2, varscan2
- ADAMTS8 | c.257del p.G86Afs*21 | Frame Shift Del (DEL) | VAF 80/593 reads (13%) | catalogued as rs1177612017, COSV57294371; called by mutect2, pindel, varscan2
- ADCY1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 329/649 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1315195968; called by muse, mutect2, varscan2
- ADGRB2 | c.4294G>A p.A1432T | Missense Mutation (SNP) | VAF 202/411 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.125); catalogued as rs756351722, COSV57070197, COSV57070479; called by muse, mutect2, varscan2
- ADGRE2 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs757107458, COSV100215746; called by muse, mutect2, varscan2
- ADGRL2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54677127; called by muse, mutect2
- ADGRL3 | c.2645T>G p.F882C (on ENST00000506720 / NM_001322402.2; = p.F814C on NM_015236.6) | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101547327; called by muse, mutect2, varscan2
- ADORA2A | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 215/429 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as rs746275437, COSV58379837; called by muse, mutect2, varscan2
- AFF2 | c.3589G>A p.A1197T | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs373659849, COSV53996724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AFF4 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 32/390 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.092); catalogued as rs777920394; called by muse, mutect2
- AGAP6 | c.988A>G p.T330A (on ENST00000374056 / NM_001365867.1; = p.T353A on NM_001077665.2) | Missense Mutation (SNP) | VAF 121/739 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs16914212, COSV100929116; called by muse, mutect2, varscan2
- AGPAT1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 245/506 reads (48%) | catalogued as COSV61247932; called by muse, mutect2, varscan2
- AHDC1 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 239/508 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1283205130; called by muse, mutect2, varscan2
- AKAP10 | c.1275A>T p.Q425H | Missense Mutation (SNP) | VAF 158/325 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV56731906; called by muse, mutect2, varscan2
- AKAP13 | c.1087_1089del p.E363del | In Frame Del (DEL) | VAF 98/212 reads (46%) | catalogued as rs747808454; called by pindel, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 131/298 reads (44%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL031777.2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 123/268 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as rs770663132, COSV61911486; called by muse, mutect2, varscan2
- AL049569.3 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 62/552 reads (11%) | catalogued as COSV100453839; called by muse, mutect2
- ALG12 | c.768+1dup p.X256_splice | Splice Site (INS) | VAF 132/319 reads (41%) | catalogued as rs762397075; called by mutect2, pindel, varscan2
- AMOTL2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs369381825; called by muse, mutect2, varscan2
- ANKRD18A | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1445234878; called by muse, varscan2
- ANKRD52 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 200/406 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464677127; called by muse, mutect2, varscan2
- ANO1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 282/636 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as rs1158620064; called by muse, mutect2, varscan2
- ANO1 | c.2698C>A p.L900M | Missense Mutation (SNP) | VAF 96/180 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV62444063; called by muse, mutect2, varscan2
- ANO2 | c.1853G>A p.R618H (on ENST00000356134 / NM_001278597.3; = p.R622H on NM_001278596.3) | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as rs373395051, COSV59049533; called by muse, mutect2, varscan2
- ANO2 | c.1004G>A p.R335H (on ENST00000356134 / NM_001278597.3; = p.R339H on NM_001278596.3) | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); catalogued as rs1486183196, COSV59028580; called by muse, mutect2, varscan2
- ANOS1 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 161/378 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); catalogued as rs201842998, COSV52918569, COSV52928370; called by muse, mutect2, varscan2
- ANTXR1 | c.1330del p.R444Gfs*18 | Frame Shift Del (DEL) | VAF 120/268 reads (45%) | catalogued as rs1558628099, COSV58013926; called by mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 80/166 reads (48%) | catalogued as rs759218332; called by mutect2, varscan2
- AP4M1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 185/417 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141331558, COSV100384643; called by muse, mutect2, varscan2
- AP5Z1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 35/619 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs769661656, COSV100804291; called by muse, mutect2
- APC | c.3778C>T p.Q1260* | Nonsense Mutation (SNP) | VAF 112/210 reads (53%) | catalogued as CD941589, COSV57348518; called by muse, mutect2, varscan2
- APLP1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1389645984; called by muse, mutect2
- APLP2 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 92/205 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147891906; called by muse, mutect2, varscan2
- APOB | c.11492T>C p.V3831A | Missense Mutation (SNP) | VAF 142/311 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1558560549; called by muse, mutect2, varscan2
- ARAP1 | c.748-7G>T | Splice Region (SNP) | VAF 344/724 reads (48%) | catalogued as COSV61995765; called by muse, mutect2, varscan2
- ARAP3 | c.4142T>C p.M1381T | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53353167; called by muse, mutect2
- ARHGAP20 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1270228529; called by muse, mutect2, varscan2
- ARHGAP32 | c.5624C>A p.P1875H (on ENST00000310343 / NM_001378025.1; = p.P1526H on NM_014715.4) | Missense Mutation (SNP) | VAF 25/451 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.46); catalogued as rs1186680268; called by muse, mutect2
- ARID3B | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 246/487 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs780212786; called by muse, mutect2, varscan2
- ARL14EPL | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 179/332 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199853691; called by muse, mutect2, varscan2
- ARMC5 | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 244/491 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.591); catalogued as rs1425139338; called by muse, mutect2, varscan2
- ASB13 | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 158/301 reads (52%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.515); catalogued as rs1005776785; called by muse, mutect2, varscan2
- ASB14 | c.371dup p.L124Ffs*24 (on ENST00000389601; = p.L123Ffs*24 on NM_001142733.3) | Frame Shift Ins (INS) | VAF 152/304 reads (50%) | catalogued as rs770471078; called by mutect2, varscan2
- ASTN1 | c.3428C>T p.T1143I | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV62495674; called by muse, mutect2, varscan2
- ASTN1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 169/382 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as rs1475157004; called by muse, mutect2, varscan2
- ASXL1 | c.4534G>A p.A1512T | Missense Mutation (SNP) | VAF 172/327 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs3171367; called by muse, mutect2, varscan2
- ATP13A1 | c.2570A>G p.Y857C | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs756469126; called by muse, mutect2, varscan2
- ATP1B1 | c.64_66del p.K22del | In Frame Del (DEL) | VAF 126/311 reads (41%) | catalogued as rs1255481007; called by pindel, varscan2
- ATP1B3 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs776768417; called by muse, mutect2, varscan2
- ATP2C2 | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52296254; called by muse, mutect2, varscan2
- ATP5MF | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 158/368 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs777324521; called by muse, varscan2
- ATP5PB | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 140/270 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs138675238; called by muse, mutect2, varscan2
- ATP7B | c.1637T>C p.I546T | Missense Mutation (SNP) | VAF 167/484 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CD1111096; called by muse, mutect2, varscan2
- ATP9A | c.2308C>T p.R770C | Missense Mutation (SNP) | VAF 73/537 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs138665384, COSV58772875; called by muse, mutect2, varscan2
- ATP9A | c.545dup p.N182Kfs*50 | Frame Shift Ins (INS) | VAF 108/216 reads (50%) | catalogued as rs1568825024; called by mutect2, varscan2
- ATP9B | c.2603G>A p.R868H | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs926575952, COSV56946498; called by muse, mutect2, varscan2
- AVPR2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 199/390 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs138974323, COSV61685966; called by muse, mutect2
- AXL | c.1706T>C p.M569T (on ENST00000301178 / NM_021913.5; = p.M560T on NM_001699.6) | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs913467939; called by muse, mutect2
- BAAT | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52290227; called by muse, mutect2, varscan2
- BACE1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 103/193 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs756600885, COSV100475410; called by muse, mutect2, varscan2
- BACE2 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as rs1213755891; called by muse, mutect2, varscan2
- BACE2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 135/272 reads (50%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.946); catalogued as rs549639705, COSV100161293; called by muse, mutect2, varscan2
- BAP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 188/407 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1284965361, COSV99964338; called by muse, mutect2, varscan2
- BCL11B | c.1223C>T p.P408L (on ENST00000357195 / NM_001282237.2; = p.P337L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 330/644 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1452791078, COSV100596021, COSV61735906; called by muse, mutect2, varscan2
- BCL6 | c.1250C>A p.P417H | Missense Mutation (SNP) | VAF 47/431 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.58); catalogued as COSV51656304; called by muse, mutect2, varscan2
- BMP1 | c.2449G>A p.V817I | Missense Mutation (SNP) | VAF 218/473 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs543117827; called by muse, mutect2, varscan2
- BRAP | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs749457952, COSV100554160; called by muse, mutect2, varscan2
- BRINP3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV66514078; called by muse, mutect2, varscan2
- BRSK1 | c.55del p.H19Tfs*47 | Frame Shift Del (DEL) | VAF 103/269 reads (38%) | catalogued as COSV55333528; called by mutect2, pindel, varscan2
- BRWD3 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 38/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1315684063; called by muse, mutect2
- BST2 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 232/462 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs776899881; called by muse, mutect2, varscan2
- BTBD8 | c.2781del p.G929Vfs*4 (on ENST00000636805 / NM_001376131.1; = p.G416Vfs*4 on NM_015237.4) | Frame Shift Del (DEL) | VAF 100/225 reads (44%) | catalogued as COSV64883816; called by mutect2, pindel, varscan2
- C11orf97 | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs1218959866; called by muse, mutect2, varscan2
- C17orf97 | c.268dup p.R90Kfs*14 | Frame Shift Ins (INS) | VAF 175/405 reads (43%) | catalogued as rs1555539481; called by mutect2, varscan2
- C1QTNF4 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 374/758 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV56784508; called by muse, mutect2, varscan2
- C1orf112 | c.2285G>A p.R762H | Missense Mutation (SNP) | VAF 132/275 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs139434399; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 108/267 reads (40%) | catalogued as rs747496393; called by mutect2, pindel, varscan2
- C6orf132 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 296/588 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1362743264; called by muse, mutect2, varscan2
- C8B | c.1404G>C p.E468D | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100980908; called by muse, mutect2, varscan2
- CABIN1 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 224/415 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs762448140; called by muse, mutect2, varscan2
- CABIN1 | c.4094C>A p.P1365H | Missense Mutation (SNP) | VAF 183/383 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV54091099; called by muse, mutect2, varscan2
- CACFD1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 26/369 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs782672760; called by muse, mutect2
- CACNA1A | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 305/600 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1309338929, COSV64192961; called by muse, mutect2, varscan2
- CACNA1B | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 238/780 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as rs1324354103; called by muse, varscan2
- CACNA1H | c.4444C>T p.R1482* | Nonsense Mutation (SNP) | VAF 201/394 reads (51%) | catalogued as rs763390819, COSV61991971; called by muse, varscan2
- CACNA1S | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 143/311 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.98); catalogued as rs554729466, COSV62941154; called by muse, mutect2, varscan2
- CACNB1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 130/331 reads (39%) | catalogued as rs1194456402, COSV59999223; called by muse, mutect2, varscan2
- CAD | c.6614G>A p.R2205H | Missense Mutation (SNP) | VAF 118/264 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762275688, COSV53027940; called by muse, varscan2
- CAMSAP3 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 50/812 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1447000653; called by muse, mutect2
- CASD1 | c.2359A>G p.I787V | Missense Mutation (SNP) | VAF 9/231 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs1197559692; called by muse, mutect2
- CBLN2 | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 226/436 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs1173199969; called by muse, mutect2, varscan2
- CBX8 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 289/595 reads (49%) | catalogued as rs1367847432; called by muse, mutect2, varscan2
- CCDC105 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 169/320 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as rs957447707, COSV52965632; called by muse, mutect2, varscan2
- CCDC34 | c.1025G>C p.R342T | Missense Mutation (SNP) | VAF 138/260 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV60820007; called by muse, mutect2, varscan2
- CCKBR | c.564del p.Y189Tfs*59 | Frame Shift Del (DEL) | VAF 294/725 reads (41%) | catalogued as COSV58106455; called by mutect2, pindel, varscan2
- CCL14 | c.187G>A p.G63R (on ENST00000618404 / NM_032963.4; = p.G79R on NM_032962.4) | Missense Mutation (SNP) | VAF 183/356 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs778815719; called by muse, mutect2, varscan2
- CCNE1 | c.562_563del p.L188Tfs*15 | Frame Shift Del (DEL) | VAF 74/266 reads (28%) | catalogued as rs1165447822; called by pindel, varscan2
- CD2BP2 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 85/494 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs750929270, COSV59769065; called by muse, mutect2, varscan2
- CDH5 | c.1864C>T p.R622W | Missense Mutation (SNP) | VAF 228/426 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1219016714, COSV58516940; called by muse, mutect2, varscan2
- CDK13 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 127/298 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1057000, COSV51706034; called by muse, mutect2, varscan2
- CDK20 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 166/353 reads (47%) | catalogued as COSV57482145; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4673G>T p.R1558L | Missense Mutation (SNP) | VAF 162/287 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs377338416; called by muse, mutect2, varscan2
- CFP | c.146del p.G49Vfs*43 | Frame Shift Del (DEL) | VAF 196/497 reads (39%) | catalogued as rs749541242; called by mutect2, pindel, varscan2
- CGNL1 | c.3809T>C p.M1270T | Missense Mutation (SNP) | VAF 156/308 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1409273500; called by muse, mutect2, varscan2
- CHD1 | c.3960del p.E1321Kfs*22 | Frame Shift Del (DEL) | VAF 107/242 reads (44%) | catalogued as rs1561489348; called by mutect2, pindel, varscan2
- CHD8 | c.4214C>T p.T1405M (on ENST00000646647 / NM_001170629.2; = p.T1126M on NM_020920.4) | Missense Mutation (SNP) | VAF 148/285 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1428398700; called by muse, mutect2, varscan2
- CHIC1 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 292/668 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV65156157; called by mutect2, varscan2
- CHST13 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 275/572 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs200175838, COSV100080958, COSV60042104; called by muse, mutect2, varscan2
- CILP2 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 342/639 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777284567, COSV52274430; called by muse, mutect2, varscan2
- CLDND1 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 126/279 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866129045, COSV57858894; called by muse, mutect2, varscan2
- CLEC14A | c.95C>A p.S32* | Nonsense Mutation (SNP) | VAF 384/747 reads (51%) | catalogued as rs754610181; called by muse, mutect2, varscan2
- CLTC | c.4934C>A p.P1645H | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs756935113; called by muse, mutect2, varscan2
- CNDP2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 160/325 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs1244606700; called by muse, mutect2, varscan2
- CNNM1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 288/694 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as rs1564933873; called by muse, mutect2, varscan2
- CNTRL | c.5309G>A p.R1770Q | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs756649801, COSV53046114; called by muse, mutect2, varscan2
- COIL | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 143/292 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV53594189; called by muse, mutect2, varscan2
- COL11A2 | c.2843dup p.P950Afs*19 (on ENST00000341947 / NM_080680.3; = p.P843Afs*19 on NM_080679.2) | Frame Shift Ins (INS) | VAF 186/527 reads (35%) | catalogued as COSV100554000; called by mutect2, pindel, varscan2
- COL12A1 | c.6066G>A p.T2022= | Splice Region (SNP) | VAF 101/270 reads (37%) | catalogued as rs754929219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 126/428 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs1415214085, COSV59397029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 243/544 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401231530; called by muse, mutect2, varscan2
- COL4A5 | c.3493G>A p.E1165K | Missense Mutation (SNP) | VAF 191/382 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.867); catalogued as rs771538814, COSV60356642; called by muse, mutect2, varscan2
- COL5A1 | c.5458T>G p.F1820V | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CD133008; called by muse, mutect2
- COL7A1 | c.5437C>A p.L1813I | Missense Mutation (SNP) | VAF 172/387 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100095011; called by muse, mutect2, varscan2
- COL7A1 | c.3850G>A p.G1284S | Missense Mutation (SNP) | VAF 224/456 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs764353299; called by muse, mutect2, varscan2
- COL9A1 | c.848dup p.G284Wfs*11 | Frame Shift Ins (INS) | VAF 126/317 reads (40%) | catalogued as rs941174282; called by pindel, varscan2
- CPAMD8 | c.2150G>A p.R717Q (on ENST00000651564; = p.R670Q on NM_015692.5) | Missense Mutation (SNP) | VAF 206/431 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as rs193060783; called by muse, mutect2, varscan2
- CPEB3 | c.1786G>A p.V596M | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56455679; called by muse, mutect2, varscan2
- CRB2 | c.3313C>T p.R1105C | Missense Mutation (SNP) | VAF 298/628 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1367901329; called by muse, varscan2
- CREB3L4 | c.715_717del p.K239del | In Frame Del (DEL) | VAF 62/213 reads (29%) | catalogued as rs749320152; called by pindel, varscan2
- CSTF3 | c.613del p.M205* | Frame Shift Del (DEL) | VAF 79/202 reads (39%) | catalogued as rs1300471016; called by mutect2, varscan2
- CT47B1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 327/689 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs776414588; called by muse, mutect2, varscan2
- CTU1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 345/728 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1439149484; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 53/130 reads (41%) | catalogued as rs772257590; called by mutect2, varscan2
- CXCL14 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1413013921; called by muse, mutect2, varscan2
- CXCL5 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.379); catalogued as rs775499405, COSV56018351; called by muse, varscan2
- CXorf56 | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 134/281 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57438655; called by muse, mutect2, varscan2
- CYFIP2 | c.3218G>A p.R1073H (on ENST00000616178 / NM_001291722.2; = p.R1048H on NM_014376.4) | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV59033187; called by muse, mutect2
- CYP17A1 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1250463562, CM920226, COSV64004840; called by muse, mutect2, varscan2
- CYP2A6 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 176/475 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV56533848; called by muse, varscan2
- CYP2S1 | c.1415T>G p.L472R | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV59507152; called by muse, mutect2, varscan2
- DCAF12 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs200315757, COSV63511596; called by muse, mutect2, varscan2
- DCAF4L2 | c.1006T>C p.C336R | Missense Mutation (SNP) | VAF 196/412 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60479796; called by muse, mutect2, varscan2
- DCAF7 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 108/212 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs778766031; called by muse, varscan2
- DDHD1 | c.2007A>C p.K669N (on ENST00000323669; = p.K866N on NM_030637.3) | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.361); catalogued as rs774311230; called by muse, varscan2
- DDX51 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 313/666 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1229979125; called by muse, mutect2, varscan2
- DEGS2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 326/627 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1490294231, COSV59785386; called by muse, mutect2
- DENND4B | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 37/548 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.058); catalogued as rs1487074819, COSV63408873, COSV63409507; called by muse, mutect2
- DENND4C | c.4040C>A p.P1347H (on ENST00000434457 / NM_001330640.2; = p.P1298H on NM_017925.7) | Missense Mutation (SNP) | VAF 133/267 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100727341; called by muse, mutect2, varscan2
- DGKB | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 207/408 reads (51%) | catalogued as COSV51761564, COSV51781556; called by muse, mutect2, varscan2
- DISP2 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs775657161, COSV51147270; called by muse, mutect2, varscan2
- DLL3 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 179/389 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs774019112; called by muse, mutect2, varscan2
- DMBT1 | c.6767G>A p.C2256Y (on ENST00000338354 / NM_001377530.1; = p.C1499Y on NM_004406.3) | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57536427; called by muse, mutect2, varscan2
- DMRTB1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 284/572 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV101008283; called by muse, varscan2
- DNAH5 | c.12059T>C p.M4020T | Missense Mutation (SNP) | VAF 88/184 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs758311625; called by muse, mutect2, varscan2
- DNAH5 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 151/368 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as rs371414060; called by muse, mutect2
- DNAJB11 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 113/222 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1291035657, COSV54003709; called by muse, mutect2, varscan2
- DNAJC7 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 120/271 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as rs1555647571; called by muse, mutect2, varscan2
- DOCK1 | c.4075T>C p.Y1359H | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.335); catalogued as rs1326738890; called by muse, mutect2
- DPYD | c.1475C>T p.S492L | Missense Mutation (SNP) | VAF 133/263 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs72549304, CM024470, COSV64594416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYSL3 | c.1648C>T p.R550C | Missense Mutation (SNP) | VAF 100/240 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs998856637; called by muse, varscan2
- DSCAML1 | c.6137del p.P2046Qfs*45 (on ENST00000321322; = p.P1986Qfs*45 on NM_020693.4) | Frame Shift Del (DEL) | VAF 85/154 reads (55%) | catalogued as rs1345834453; called by mutect2, varscan2
- DTX1 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 208/444 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs1269908567; called by muse, mutect2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 78/168 reads (46%) | catalogued as rs768937539; called by mutect2*, varscan2
- E2F3 | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 159/325 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60895762; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs138050343; called by muse, mutect2, varscan2
- EGR4 | c.1437C>G p.H479Q (on ENST00000545030; = p.H376Q on NM_001965.4) | Missense Mutation (SNP) | VAF 271/541 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101474202; called by muse, mutect2, varscan2
- EIF4G1 | c.3613C>T p.R1205C (on ENST00000346169 / NM_198241.3; = p.R1010C on NM_004953.5) | Missense Mutation (SNP) | VAF 146/278 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs776741558, CM131885, COSV59990924; called by muse, mutect2, varscan2
- ELOA2 | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 282/522 reads (54%) | catalogued as rs1369469159; called by muse, mutect2, varscan2
- EMB | c.821T>C p.L274S | Missense Mutation (SNP) | VAF 152/277 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs554905296; called by muse, mutect2, varscan2
- EMILIN2 | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 177/363 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs768102952, COSV54424565; called by muse, mutect2, varscan2
- EN1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54630875; called by muse, mutect2, varscan2
- ENO4 | c.1759dup p.Y587Lfs*3 (on ENST00000622726; = p.Y584Lfs*3 on NM_001242699.2) | Frame Shift Ins (INS) | VAF 93/182 reads (51%) | catalogued as rs763733545; called by mutect2, varscan2
- EPB41L3 | c.876dup p.L293Ifs*12 | Frame Shift Ins (INS) | VAF 131/311 reads (42%) | catalogued as rs1484979313; called by mutect2, pindel, varscan2
- EPHA3 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 112/253 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs933501529; called by muse, mutect2, varscan2
- EPHB2 | c.631C>A p.L211M | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV65863714; called by muse, mutect2
- EPN3 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 230/449 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs746817179, COSV52143191; called by muse, mutect2, varscan2
- EPPK1 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs781948875; called by muse, mutect2
- EPS15L1 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 40/526 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs756438586; called by muse, mutect2
- ERBB4 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs371593463, COSV53572221; called by muse, varscan2
- ERN1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 102/210 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs200474313; called by muse, mutect2, varscan2
- ESPNL | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 211/427 reads (49%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.59); catalogued as rs1040528544; called by muse, mutect2, varscan2
- EXO5 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 166/372 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs767242814; called by muse, mutect2
- EXOC3L1 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 165/329 reads (50%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.896); catalogued as rs1036212047; called by muse, mutect2, varscan2
- EXOC3L4 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 328/656 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66295499; called by muse, varscan2
- EXT2 | c.1139T>C p.I380T (on ENST00000343631; = p.I413T on NM_000401.3) | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as CM014568; called by muse, mutect2, varscan2
- FAM170B | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 241/509 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs1256901590, COSV61253650, COSV61253833, COSV61254012; called by muse, mutect2, varscan2
- FAM171A2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 26/446 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.721); catalogued as rs1273058713; called by muse, mutect2
- FAM50B | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 188/386 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV66654701; called by muse, mutect2, varscan2
- FANCG | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 129/267 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs746248064; called by muse, mutect2, varscan2
- FAT4 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.653); catalogued as COSV67880854; called by muse, mutect2
- FBXO38 | c.2387G>A p.R796H | Missense Mutation (SNP) | VAF 187/369 reads (51%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.385); catalogued as rs765335278; called by muse, mutect2, varscan2
- FBXO41 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 131/282 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs865871335, COSV54590221; called by muse, mutect2, varscan2
- FBXW7 | c.652C>T p.Q218* (on ENST00000281708 / NM_001349798.2; = p.Q138* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 152/331 reads (46%) | catalogued as COSV55911149; called by muse, mutect2, varscan2
- FDX2 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 211/456 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as rs770890120; called by mutect2, varscan2
- FDXR | c.1156C>T p.R386W (on ENST00000293195 / NM_024417.5; = p.R392W on NM_004110.6) | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as rs760345680; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775900978, COSV61595320; called by muse, mutect2, varscan2
- FICD | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 174/384 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs747434780, COSV99934253; called by muse, mutect2, varscan2
- FLNA | c.6019G>A p.V2007M (on ENST00000369850 / NM_001110556.2; = p.V1999M on NM_001456.3) | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs200956777, COSV61042743; called by muse, mutect2, varscan2
- FLNB | c.3733C>T p.R1245W | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371186570; called by muse, mutect2, varscan2
- FLNC | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 140/324 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs751493542; called by muse, mutect2, varscan2
- FLOT2 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 221/468 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs369702593; called by muse, mutect2, varscan2
- FLT1 | c.3731G>A p.G1244D | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1315888360, COSV99169366; called by muse, mutect2, varscan2
- FLYWCH1 | c.494G>A p.R165Q (on ENST00000253928 / NM_001308068.2; = p.R164Q on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 305/612 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371073892; called by muse, varscan2
- FLYWCH1 | c.523G>A p.A175T (on ENST00000253928 / NM_001308068.2; = p.A174T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 294/590 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs780307376, COSV99558652; called by muse, varscan2
- FOSL1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100440939; called by muse, mutect2
- FOXE1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 267/579 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64300793; called by muse, mutect2
- FOXK2 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 164/332 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150409126; called by muse, mutect2, varscan2
- FREM2 | c.7061C>T p.T2354M | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as rs775634507, COSV54834522; called by muse, mutect2, varscan2
- FRMPD3 | c.4499C>T p.A1500V | Missense Mutation (SNP) | VAF 242/501 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as COSV99346962; called by muse, mutect2, varscan2
- FTCD | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 290/586 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs776013471, COSV52425107, COSV52431419; called by muse, mutect2, varscan2
- G2E3 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746122872, COSV52840270; called by muse, mutect2
- GAA | c.1772G>A p.R591Q | Missense Mutation (SNP) | VAF 178/392 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs528010457, COSV56409964; called by muse, varscan2
- GATA2 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 180/378 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); catalogued as rs1262581730; called by muse, mutect2, varscan2
- GCNT2 | c.962G>A p.G321E (on ENST00000379597 / NM_001374747.1; = p.G319E on NM_001491.3) | Missense Mutation (SNP) | VAF 98/225 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV53942844; called by muse, mutect2, varscan2
- GFUS | c.224del p.G75Afs*19 | Frame Shift Del (DEL) | VAF 218/446 reads (49%) | catalogued as rs768502029; called by mutect2, varscan2
- GLI3 | c.4364C>T p.T1455M | Missense Mutation (SNP) | VAF 34/455 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs1016873543, COSV104431684; called by muse, mutect2
- GLUD1 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as rs747542852, COSV104375284; called by mutect2, varscan2
- GNAS | c.1643C>T p.A548V | Missense Mutation (SNP) | VAF 285/590 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as rs767898826, COSV58342186, COSV58342626; called by muse, mutect2, varscan2
- GOLGA3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 203/421 reads (48%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as rs201001117; called by muse, mutect2, varscan2
- GPBAR1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 20/625 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs907641202, COSV99946170; called by muse, mutect2
- GPR25 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 203/419 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as rs370410174, COSV104412766; called by muse, mutect2, varscan2
- GPT2 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 111/218 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772285948, COSV60839199; called by muse, mutect2, varscan2
- GRAMD1B | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 190/400 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs776432140; called by muse, mutect2, varscan2
- GRID1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 252/524 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs866578461; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 157/169 reads (93%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 143/278 reads (51%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN3B | c.2914G>A p.A972T | Missense Mutation (SNP) | VAF 433/839 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1271178770; called by muse, mutect2, varscan2
- GRM1 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 169/376 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51310207, COSV99266741; called by muse, varscan2
- GRM2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs1160790431, COSV56585962, COSV56588122; called by muse, mutect2, varscan2
- GRM6 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 162/352 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as rs755386646, COSV51443174; called by muse, varscan2
- GRM7 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 221/444 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as rs1055345234, COSV63143160; called by muse, mutect2, varscan2
- GRSF1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs368531595; called by muse, mutect2, varscan2
- GUCY2D | c.2836G>A p.A946T | Missense Mutation (SNP) | VAF 234/468 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV54696975; called by muse, mutect2, varscan2
- HADHA | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs979643559; called by muse, mutect2
- HCN1 | c.332T>A p.L111H | Missense Mutation (SNP) | VAF 246/522 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV57531434; called by muse, varscan2
- HDGF | c.149del p.F50Sfs*105 | Frame Shift Del (DEL) | VAF 124/214 reads (58%) | catalogued as COSV100625709; called by mutect2, varscan2
- HECTD4 | c.8455C>T p.R2819* | Nonsense Mutation (SNP) | VAF 133/326 reads (41%) | catalogued as COSV66386558; called by muse, mutect2, varscan2
- HELT | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 252/548 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58820243; called by muse, mutect2, varscan2
- HELZ2 | c.7448C>T p.T2483M (on ENST00000467148 / NM_001037335.2; = p.T1914M on NM_033405.3) | Missense Mutation (SNP) | VAF 230/464 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs372227006; called by muse, varscan2
- HELZ2 | c.6674C>T p.S2225L (on ENST00000467148 / NM_001037335.2; = p.S1656L on NM_033405.3) | Missense Mutation (SNP) | VAF 225/478 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1170034006, COSV101427510; called by muse, mutect2, varscan2
- HEPHL1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.661); catalogued as rs765796645, COSV59889960; called by muse, mutect2, varscan2
- HERC1 | c.13225G>T p.D4409Y | Missense Mutation (SNP) | VAF 163/339 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV71249821; called by muse, mutect2, varscan2
- HGS | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 226/453 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs766038236; called by muse, mutect2, varscan2
- HLA-DOA | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 168/356 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as rs913428613; called by muse, mutect2
- HLF | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776917251, COSV56828344, COSV99872274; called by muse, mutect2, varscan2
- HMCN1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 92/233 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as rs369085610; called by muse, mutect2, varscan2
- HMCN1 | c.8093C>T p.A2698V | Missense Mutation (SNP) | VAF 106/240 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs1208182724, COSV54882114; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs761733009, COSV57131444; called by muse, mutect2, varscan2
- HOXC13 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 231/498 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs759565446, COSV54498442; called by muse, mutect2, varscan2
- HSPA1L | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 214/421 reads (51%) | catalogued as rs1292518532, COSV65149424; called by muse, mutect2, varscan2
- HSPA1L | c.784G>A p.V262M | Missense Mutation (SNP) | VAF 239/510 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.698); catalogued as rs142416335; called by muse, mutect2, varscan2
- HSPB8 | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 178/404 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs200120006, COSV104440674; called by muse, mutect2, varscan2
- ICAM2 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 189/366 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs773254258, COSV99857077; called by muse, mutect2, varscan2
- IDH2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1227626398, COSV57472218; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGF1R | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 165/323 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121912426, CM035076; ClinVar: protective; called by muse, mutect2, varscan2
- IGFBP1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 181/407 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs76681789; called by muse, mutect2, varscan2
- IGHG1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 82/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767020568; called by muse, mutect2
- IGHG4 | c.350del p.G117Dfs*16 | Frame Shift Del (DEL) | VAF 159/384 reads (41%) | catalogued as rs1475796782; called by mutect2, pindel, varscan2
- IGHMBP2 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 210/417 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201054207, COSV54825451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGLV3-19 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs770190512; called by muse, mutect2, varscan2
- IL17RA | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 164/340 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as COSV100083450; called by muse, mutect2, varscan2
- IL31RA | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs768209580, COSV51681241; called by muse, mutect2, varscan2
- INCA1 | c.286C>T p.P96S (on ENST00000574617 / NM_001167986.1; = p.P81S on NM_213726.2) | Missense Mutation (SNP) | VAF 197/389 reads (51%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as rs756594275; called by muse, mutect2, varscan2
- INF2 | c.1864del p.R622Gfs*18 | Frame Shift Del (DEL) | VAF 188/458 reads (41%) | catalogued as rs1459726028; called by mutect2, pindel, varscan2
- INHA | c.197del p.G66Afs*61 | Frame Shift Del (DEL) | VAF 220/562 reads (39%) | catalogued as rs1190141661; called by mutect2, pindel, varscan2
- INSL6 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 187/358 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.059); catalogued as rs539770695; called by muse, mutect2, varscan2
- INTS1 | c.4561G>A p.V1521I | Missense Mutation (SNP) | VAF 247/512 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs759138761, COSV67177245; called by muse, mutect2, varscan2
- INTS9 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs758455209, COSV68433312; called by muse, mutect2, varscan2
- IPO5 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 52/924 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.157); catalogued as rs766125750; called by muse, mutect2
- IPO7 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.221); catalogued as rs1173346441, COSV101121850; called by muse, mutect2, varscan2
- IQSEC1 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 126/268 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755905106, COSV56225506; called by muse, mutect2, varscan2
- IRAG1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 156/316 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368966460, COSV70211482; called by muse, varscan2
- IRX6 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 61/608 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs780746131, COSV51858932; called by muse, mutect2, varscan2
- ITGB3 | c.914A>G p.N305S | Missense Mutation (SNP) | VAF 127/296 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs768677385; called by muse, mutect2, varscan2
- ITGBL1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs765315193, COSV66007930, COSV66011288; called by muse, mutect2, varscan2
- JARID2 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 144/276 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs1316410441, COSV59185823; called by muse, mutect2, varscan2
- KATNAL1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 200/328 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs201513671, COSV66062824; called by muse, varscan2
- KBTBD13 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 258/581 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1177976401, COSV71351768; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 182/384 reads (47%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNG2 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 58/718 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60266939; called by muse, mutect2
- KCNJ4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 207/431 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1416311952, COSV100341106, COSV100341516; called by muse, mutect2, varscan2
- KCNQ2 | c.1325G>A p.R442H (on ENST00000359125 / NM_172107.4; = p.R414H on NM_004518.6) | Missense Mutation (SNP) | VAF 44/478 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1262943594, COSV60547722; called by muse, mutect2
- KCNQ2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 410/828 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1064797286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNV2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 284/594 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs751709716; called by muse, varscan2
- KCP | c.3568G>A p.V1190M (on ENST00000620378; = p.V1314M on NM_001366122.1) | Missense Mutation (SNP) | VAF 219/450 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1183776703; called by muse, mutect2, varscan2
- KDM2A | c.2540G>A p.R847H | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs774576742; called by muse, varscan2
- KDM5C | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 191/393 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1556839568, COSV64770829; called by muse, mutect2, varscan2
- KDM6B | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 235/480 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs377714300; called by muse, varscan2
- KDM6B | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 317/662 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as rs925720057; called by muse, mutect2, varscan2
- KIF13A | c.1911del p.D638Tfs*23 | Frame Shift Del (DEL) | VAF 179/376 reads (48%) | catalogued as COSV99435367, COSV99438034; called by mutect2, varscan2
- KIFC3 | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 141/285 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs554025520, COSV65548640, COSV65553898; called by muse, mutect2, varscan2
- KLHL21 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 229/491 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs772447646; called by muse, varscan2
- KLHL22 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 211/398 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs780696914, COSV61022511; called by muse, mutect2, varscan2
- KMT2C | c.2386A>G p.M796V | Missense Mutation (SNP) | VAF 41/412 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs773544755, COSV51355046, COSV51434940, COSV51484696; called by muse, mutect2, varscan2
- KMT2C | c.57del p.E20Rfs*85 | Frame Shift Del (DEL) | VAF 220/569 reads (39%) | catalogued as COSV100067709, COSV51402237; called by mutect2, pindel, varscan2
- KRT3 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 392/771 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs772879943, COSV58814764; called by muse, mutect2, varscan2
- KRTAP4-5 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 300/631 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs893284376, COSV58354098; called by muse, mutect2, varscan2
- LAG3 | c.835G>T p.G279W | Missense Mutation (SNP) | VAF 209/415 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV52569219; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 63/197 reads (32%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LDAH | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 102/244 reads (42%) | catalogued as rs746735962, COSV52970099; called by muse, mutect2, varscan2
- LDB1 | c.843G>T p.M281I (on ENST00000425280 / NM_001321612.2; = p.M245I on NM_003893.5) | Missense Mutation (SNP) | VAF 104/217 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as COSV100756369; called by muse, mutect2, varscan2
- LDLRAD4 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1264139988, COSV100762154; called by muse, mutect2
- LGI1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 166/344 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs201376381, COSV65057719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LHX1 | c.361A>G p.N121D | Missense Mutation (SNP) | VAF 219/493 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.324); catalogued as rs200877362; called by muse, mutect2, varscan2
- LHX2 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65318782; called by muse, mutect2
- LIFR | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 116/296 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as rs749594956; called by muse, mutect2, varscan2
- LIG3 | c.2554G>A p.G852S | Missense Mutation (SNP) | VAF 168/333 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs138909084; called by muse, mutect2, varscan2
- LMNB2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 41/355 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs755832231, COSV57590051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMX1A | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 128/288 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs756064889; called by muse, mutect2, varscan2
- LOXHD1 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs570602921, COSV56060084; called by muse, mutect2, varscan2
- LOXL2 | c.2276del p.K759Sfs*9 | Frame Shift Del (DEL) | VAF 144/334 reads (43%) | catalogued as rs765428971; called by mutect2, pindel, varscan2
- LRFN4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 287/627 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV58921441; called by muse, mutect2, varscan2
- LRP1 | c.8425G>A p.A2809T | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs748229333, COSV99677689; called by muse, mutect2
- LRP2 | c.3617G>A p.R1206H | Missense Mutation (SNP) | VAF 144/315 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs377534549; ClinVar: uncertain significance; called by muse, mutect2
- LRPAP1 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 283/527 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs756067957; called by muse, mutect2, varscan2
- LRRC14 | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 268/530 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs776222160, COSV52880015; called by muse, varscan2
- LRRC7 | c.793G>T p.G265W (on ENST00000651989 / NM_001370785.2; = p.G232W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50453892; called by muse, mutect2, varscan2
- LSS | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 172/340 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs903364744, COSV62701118; called by muse, varscan2
- LTBP1 | c.674A>G p.D225G | Missense Mutation (SNP) | VAF 167/373 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs894875974; called by muse, mutect2, varscan2
- LTBP3 | c.3810C>A p.S1270R (on ENST00000301873 / NM_001130144.3; = p.S1223R on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 269/566 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV54212801; called by mutect2, varscan2
- MAP2K3 | c.455G>A p.R152Q (on ENST00000342679 / NM_145109.3; = p.R123Q on NM_002756.4) | Missense Mutation (SNP) | VAF 68/376 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs148304866; called by muse, mutect2
- MAP2K6 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs144625593; called by muse, mutect2, varscan2
- MAP3K6 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 350/726 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as rs771814936, COSV100709054; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 27/71 reads (38%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 145/283 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs373144666; called by muse, mutect2, varscan2
- MARK4 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750744530; called by muse, mutect2, varscan2
- MAST2 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 154/330 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs754083908; called by muse, mutect2, varscan2
- MAST3 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV53223919; called by muse, mutect2, varscan2
- MATK | c.949C>T p.R317W (on ENST00000310132 / NM_139355.3; = p.R318W on NM_002378.4) | Missense Mutation (SNP) | VAF 42/466 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs770236693; called by muse, mutect2
- MB21D2 | c.491G>A p.C164Y | Missense Mutation (SNP) | VAF 154/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66665522; called by muse, mutect2, varscan2
- MBOAT7 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 337/676 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs962176750; called by muse, mutect2, varscan2
- MBP | c.799G>A p.D267N (on ENST00000355994 / NM_001025101.2; = p.D149N on NM_002385.3) | Missense Mutation (SNP) | VAF 182/394 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); catalogued as rs1384383051, COSV100592573; called by muse, mutect2, varscan2
- MCC | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 128/297 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.441); catalogued as COSV56737064; called by muse, mutect2, varscan2
- MCC | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs867520561; called by muse, mutect2, varscan2
- MCCC1 | c.884A>G p.K295R | Missense Mutation (SNP) | VAF 87/189 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99659494; called by muse, mutect2, varscan2
- MDGA1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 26/917 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as rs894829516; called by muse, mutect2
- MDN1 | c.14287A>G p.M4763V | Missense Mutation (SNP) | VAF 50/686 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769098735; called by muse, mutect2
- MDN1 | c.14143G>A p.D4715N | Missense Mutation (SNP) | VAF 132/395 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs756583792; called by muse, mutect2, varscan2
- MED15 | c.1873G>A p.V625I (on ENST00000263205 / NM_001003891.3; = p.V585I on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/658 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1018320157, COSV53028325; called by muse, mutect2, varscan2
- MEGF10 | c.3316C>T p.H1106Y | Missense Mutation (SNP) | VAF 145/302 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57251599; called by muse, mutect2, varscan2
- MEGF8 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 45/640 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs926015247, COSV52075537; called by muse, mutect2
- MERTK | c.2386C>T p.R796W | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539760413, COSV54937334; called by muse, mutect2, varscan2
- MEX3D | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 258/555 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as rs766880045, COSV104429447; called by muse, mutect2, varscan2
- MLLT1 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV53131013; called by muse, mutect2, varscan2
- MLLT3 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 51/448 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs1451763404; called by muse, varscan2
- MOB3A | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 220/461 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs762298832; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 77/173 reads (45%) | catalogued as rs755830405; called by mutect2, varscan2
- MRC2 | c.519C>T p.H173= | Splice Region (SNP) | VAF 110/213 reads (52%) | catalogued as rs140481613; called by muse, mutect2, varscan2
- MROH2A | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 256/557 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs1234437711; called by muse, mutect2, varscan2
- MS4A7 | c.476T>C p.L159S | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs771464648; called by muse, mutect2, varscan2
- MSRB3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 191/413 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV57587111; called by muse, mutect2, varscan2
- MTHFD1L | c.2899C>T p.L967F | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66225227; called by muse, mutect2, varscan2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 158/367 reads (43%) | catalogued as COSV67467225; called by mutect2, pindel, varscan2
- MUC6 | c.5225C>T p.T1742M | Missense Mutation (SNP) | VAF 234/1666 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs372353242, COSV101424324; called by muse, varscan2
- MUCL3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 310/624 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs1179386202; called by muse, mutect2, varscan2
- MYBPC3 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 207/421 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.92); catalogued as CM102774; called by muse, mutect2, varscan2
- MYH11 | c.4765_4767del p.E1589del | In Frame Del (DEL) | VAF 130/314 reads (41%) | catalogued as rs773606406; called by pindel, varscan2
- MYOF | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774992910, COSV63710308; called by muse, mutect2, varscan2
- MYPN | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs199476416, CM122988, COSV62731805; called by muse, mutect2, varscan2
- MZF1 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 36/540 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs758062386; called by muse, mutect2
- NAALADL2 | c.2385T>A p.N795K | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV71986889; called by muse, mutect2, varscan2
- NACC2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 266/549 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs965015333, COSV53201958; called by muse, mutect2, varscan2
- NAPA | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 147/320 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as rs762076236, COSV54552033; called by muse, mutect2, varscan2
- NBEA | c.6548A>T p.D2183V | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs369385598; called by muse, mutect2
- NCOR1 | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 147/302 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1406850631, COSV51964364; called by muse, mutect2, varscan2
- NDOR1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 129/292 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs1229086744, COSV61286457; called by muse, mutect2, varscan2
- NDST3 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs764215296, COSV56615244; called by muse, varscan2
- NEB | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs751875993, COSV51128774; called by muse, mutect2, varscan2
- NEDD4 | c.2971C>T p.R991* (on ENST00000508342 / NM_001284338.1; = p.R572* on NM_006154.4) | Nonsense Mutation (SNP) | VAF 207/411 reads (50%) | catalogued as rs773579050; called by muse, mutect2, varscan2
- NEK10 | c.2569C>T p.L857F | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs1470117093; called by muse, mutect2, varscan2
- NELL2 | c.2062del p.C688Afs*90 | Frame Shift Del (DEL) | VAF 120/315 reads (38%) | catalogued as rs34674438; called by mutect2, pindel, varscan2
- NEURL4 | c.4162C>T p.R1388W | Missense Mutation (SNP) | VAF 38/508 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs761529197; called by muse, mutect2
- NFATC1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 269/605 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs372719440; called by muse, mutect2
- NFATC2 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 177/374 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65361952; called by muse, mutect2, varscan2
- NKX1-1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 288/597 reads (48%) | SIFT deleterious, low confidence (0); catalogued as rs1191765976; called by muse, mutect2, varscan2
- NLRP1 | c.3059C>T p.A1020V | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs777794047; called by muse, mutect2, varscan2
- NOBOX | c.1322dup p.L442Tfs*35 | Frame Shift Ins (INS) | VAF 37/78 reads (47%) | catalogued as rs753934412; called by mutect2, varscan2
- NOMO1 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1358306425; called by muse, mutect2, varscan2
- NPBWR1 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 231/459 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as rs1457133051, COSV58696356; called by muse, mutect2, varscan2
- NPFFR1 | c.758del p.G253Afs*207 | Frame Shift Del (DEL) | VAF 273/712 reads (38%) | catalogued as rs1337560807; called by mutect2, pindel, varscan2
- NPR3 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 198/421 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV54085854; called by muse, mutect2, varscan2
- NR1D2 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 124/262 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs1346281504; called by muse, mutect2, varscan2
- NRK | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 232/482 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99688249; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 154/325 reads (47%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTHL1 | c.488G>T p.S163I (on ENST00000219066; = p.S155I on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/529 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as COSV54593808; called by muse, mutect2
- NTM | c.16T>C p.Y6H | Missense Mutation (SNP) | VAF 112/267 reads (42%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs771706811; called by muse, mutect2, varscan2
- NUDCD1 | c.337A>G p.N113D | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs777060686; called by muse, mutect2, varscan2
- NUP133 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs756200848; called by muse, mutect2, varscan2
- NUP210 | c.3140G>A p.R1047H | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs569525173, COSV54410271; called by muse, mutect2, varscan2
- NXPE2 | c.379dup p.D127Gfs*43 | Frame Shift Ins (INS) | VAF 143/392 reads (36%) | catalogued as rs1178462460; called by pindel, varscan2
- OCSTAMP | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 213/438 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1162621646, COSV54097165; called by muse, varscan2
- OPN4 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 246/482 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs753202138, COSV54116993; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 176/442 reads (40%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR1J2 | c.321del p.F107Lfs*30 | Frame Shift Del (DEL) | VAF 42/337 reads (12%) | catalogued as COSV99080418; called by mutect2, pindel, varscan2
- OR2A7 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 123/565 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as rs746057809, COSV101512224; called by muse, mutect2, varscan2
- OR2I1P | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 54/555 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1352620145; called by muse, mutect2
- OR2W3 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 129/284 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.182); catalogued as rs369250388, COSV64456271; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 128/278 reads (46%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52J3 | c.933del p.K311Nfs*? | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | catalogued as rs1254479213; called by mutect2, pindel, varscan2
- OR52L1 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 110/255 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59986903; called by muse, mutect2, varscan2
- OR5B12 | c.597del p.F199Lfs*13 | Frame Shift Del (DEL) | VAF 114/200 reads (57%) | catalogued as rs747074822; called by mutect2, varscan2
- OR5V1 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197692632; called by muse, mutect2
- OR7E24 | c.504del p.F168Lfs*12 | Frame Shift Del (DEL) | VAF 153/410 reads (37%) | catalogued as rs1031417078; called by mutect2, pindel, varscan2
- OTOL1 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 171/342 reads (50%) | catalogued as rs768325686; called by muse, mutect2, varscan2
- PC | c.2338G>A p.V780M | Missense Mutation (SNP) | VAF 255/561 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs572440768, COSV58992352; called by muse, mutect2, varscan2
- PCARE | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 221/417 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs750992193; called by muse, mutect2, varscan2
- PCDH10 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 70/726 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758967264; called by muse, mutect2
- PCDH11X | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV53470362, COSV53501091; called by muse, mutect2, varscan2
- PCDH17 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 149/539 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV64971354; called by muse, mutect2, varscan2
- PCDH19 | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 236/475 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720281; called by muse, mutect2, varscan2
- PCDHA11 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 170/316 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.086); catalogued as COSV56544176; called by muse, mutect2, varscan2
- PCDHA5 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 192/452 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as rs1381844487, COSV65352049; called by muse, varscan2
- PCDHA7 | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 189/387 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.946); catalogued as rs373780071, COSV65347313; called by muse, mutect2, varscan2
- PCDHA9 | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 250/510 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65324320; called by muse, mutect2, varscan2
- PCDHB7 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 160/344 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV50761582; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 334/686 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA11 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs1482347889; called by muse, mutect2, varscan2
- PCDHGB4 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 298/610 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs746309479, COSV53899447; called by muse, mutect2, varscan2
- PCGF1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.648); catalogued as rs150874982; called by muse, varscan2
- PDE6B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 226/479 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1173402643; called by muse, mutect2, varscan2
- PDGFRB | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.637); catalogued as rs747398617, COSV55801407; called by muse, mutect2, varscan2
- PDS5A | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57825147; called by muse, mutect2
- PERCC1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 338/695 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs370618058; called by muse, varscan2
- PEX5L | c.1537C>A p.R513S | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55846139, COSV99829535; called by muse, mutect2, varscan2
- PGAP4 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.263); catalogued as COSV66387869; called by muse, mutect2
- PGBD1 | c.593dup p.N198Kfs*12 | Frame Shift Ins (INS) | VAF 122/252 reads (48%) | catalogued as rs749589486; called by mutect2, varscan2
- PGBD4 | c.1487del p.K496Sfs*109 | Frame Shift Del (DEL) | VAF 131/341 reads (38%) | catalogued as rs1454502156; called by mutect2, pindel, varscan2
- PGLYRP1 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 140/278 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs771245601; called by muse, mutect2, varscan2
- PHC3 | c.832C>T p.R278* (on ENST00000494943 / NM_001308116.2; = p.R290* on NM_024947.4) | Nonsense Mutation (SNP) | VAF 119/250 reads (48%) | catalogued as rs1199650727; called by muse, mutect2, varscan2
- PHF21A | c.1955dup p.A653Cfs*22 (on ENST00000418153 / NM_001101802.3; = p.A607Cfs*22 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 202/412 reads (49%) | catalogued as rs761575760; called by mutect2, varscan2
- PHKA2 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as rs1451691248; called by muse, mutect2, varscan2
- PHKB | c.1929del p.G644Efs*2 | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | catalogued as rs35494330; called by mutect2, varscan2
- PHLDB2 | c.3515G>A p.R1172Q (on ENST00000393925 / NM_001134439.2; = p.R1129Q on NM_145753.2) | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs780008726, COSV67311993; called by muse, mutect2, varscan2
- PHOSPHO2 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs761691174; called by muse, mutect2
- PI4KA | c.4195C>T p.R1399W | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs547345219; called by muse, mutect2, varscan2
- PIH1D1 | c.743del p.G248Afs*8 | Frame Shift Del (DEL) | VAF 180/460 reads (39%) | catalogued as rs1274833333; called by mutect2, pindel, varscan2
- PIK3R2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV55848495; called by muse, mutect2, varscan2
- PIMREG | c.686G>T p.R229M (on ENST00000250056 / NM_001195228.2; = p.S229I on NM_019013.3) | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99337764; called by muse, mutect2, varscan2
- PITRM1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs753024095; called by muse, mutect2, varscan2
- PLB1 | c.4102G>T p.E1368* | Nonsense Mutation (SNP) | VAF 157/338 reads (46%) | catalogued as COSV100580176; called by muse, mutect2, varscan2
- PLCG2 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs777990663, COSV63868986; called by muse, mutect2, varscan2
- PLEKHG3 | c.733G>A p.G245R (on ENST00000394691; = p.G301R on NM_001308147.2) | Missense Mutation (SNP) | VAF 181/373 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs921162665, COSV99906233; called by muse, mutect2, varscan2
- PLEKHG6 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 202/432 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs764740431, COSV50601613; called by muse, mutect2, varscan2
- PLEKHH2 | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1486166207; called by muse, mutect2, varscan2
- PLOD3 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs774330683, COSV56184228; called by muse, mutect2, varscan2
- PLXNA4 | c.3574G>A p.V1192M | Missense Mutation (SNP) | VAF 191/421 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs759149224; called by muse, mutect2, varscan2
- PODN | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 306/664 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1445826218; called by muse, mutect2
- POGLUT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs369098373; called by muse, mutect2, varscan2
- POLA2 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 109/217 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV55481322, COSV55483568; called by muse, mutect2, varscan2
- POLD3 | c.861del p.A288Qfs*17 | Frame Shift Del (DEL) | VAF 126/291 reads (43%) | catalogued as rs1565122953; called by mutect2, pindel, varscan2
- POLE | c.5467C>T p.R1823C | Missense Mutation (SNP) | VAF 155/406 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753627422, COSV57685208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLK | c.1252G>A p.V418I | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs138877411; called by muse, mutect2, varscan2
- POLRMT | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 238/562 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs774772391; called by muse, mutect2, varscan2
- PON2 | c.195dup p.S66* | Frame Shift Ins (INS) | VAF 124/264 reads (47%) | catalogued as rs1201102139; called by mutect2, varscan2
- POTEE | c.2237del p.G746Afs*20 | Frame Shift Del (DEL) | VAF 91/478 reads (19%) | catalogued as rs1229339641; called by mutect2, pindel, varscan2
- PPP1R11 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 332/703 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.211); catalogued as rs765467277, COSV54993327; called by muse, mutect2, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as rs758484975; called by mutect2, varscan2
- PRCD | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 182/370 reads (49%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as rs768323513; called by muse, varscan2
- PRDM1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 211/408 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1439183927; called by muse, mutect2, varscan2
- PRDM13 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 335/652 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs770384917, COSV65030735; called by muse, mutect2, varscan2
- PRKAB1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 189/403 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs752474474; called by muse, mutect2, varscan2
- PRKAR2A | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 99/238 reads (42%) | catalogued as rs199701451, COSV55552459; called by muse, mutect2, varscan2
- PROX1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 170/368 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs774501972; called by muse, mutect2, varscan2
- PRR23A | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 208/432 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as rs567538155; called by muse, mutect2, varscan2
- PRRT3 | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 231/506 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs371255955; called by muse, mutect2, varscan2
- PRRT4 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 303/636 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs929972948; called by muse, mutect2, varscan2
- PSD | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 224/446 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as COSV99194092; called by muse, mutect2, varscan2
- PSD3 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as rs189891634, COSV58965108; called by muse, mutect2, varscan2
- PTCHD3 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 39/516 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs1203300848; called by muse, mutect2
- PTGDR | c.452T>C p.L151P | Missense Mutation (SNP) | VAF 32/563 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs199651150; called by muse, mutect2
- PTN | c.229A>G p.K77E | Missense Mutation (SNP) | VAF 183/362 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs1316734920; called by muse, mutect2, varscan2
- PTPRC | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 231/475 reads (49%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.062); catalogued as COSV100722226; called by muse, mutect2, varscan2
- PTPRE | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 30/507 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as rs376366402, COSV54547347; called by muse, mutect2
- PTPRN2 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs141149619; called by muse, mutect2, varscan2
- PTPRS | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 206/475 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1064293; called by muse, mutect2, varscan2
- PTPRU | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 175/400 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as rs374665975; called by muse, mutect2, varscan2
- PXDN | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 305/628 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.953); catalogued as rs370877087; called by muse, mutect2, varscan2
- QPRT | c.382dup p.A128Gfs*46 | Frame Shift Ins (INS) | VAF 246/604 reads (41%) | catalogued as rs757852504; called by mutect2, pindel, varscan2
- RABGGTA | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 176/396 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs369486237; called by muse, mutect2
- RALGDS | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 228/482 reads (47%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as rs1008744949; called by muse, mutect2, varscan2
- RASGEF1A | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 261/549 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV65667001; called by muse, mutect2, varscan2
- RASGRF1 | c.2965G>A p.D989N | Missense Mutation (SNP) | VAF 140/315 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as rs779564323, COSV67250689; called by muse, mutect2, varscan2
- RASSF8 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1439052300, COSV51453528; called by muse, mutect2, varscan2
- RAVER1 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs766758702; called by muse, mutect2, varscan2
- RAX | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 269/532 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875072, COSV56875388; called by muse, mutect2, varscan2
- RBFOX1 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 55/154 reads (36%) | catalogued as CM157820, COSV60959842; called by muse, mutect2, varscan2
- RBM12B | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 293/638 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); catalogued as rs552325394; called by muse, mutect2, varscan2
- RBM27 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs764829238, COSV54587752; called by muse, mutect2, varscan2
- RCN3 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 202/423 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs759203235, COSV54541092; called by muse, mutect2, varscan2
- RET | c.1636G>T p.G546* | Nonsense Mutation (SNP) | VAF 24/294 reads (8%) | catalogued as COSV60690542; called by muse, mutect2
- REXO4 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 195/447 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs988432346, COSV100905781; called by muse, mutect2, varscan2
- RGS12 | c.2299C>T p.R767W | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1159179946; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 99/216 reads (46%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 314/747 reads (42%) | catalogued as rs747974681; called by mutect2, pindel, varscan2
- RHBDF1 | c.2236C>T p.R746C | Missense Mutation (SNP) | VAF 181/364 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs1424100896; called by muse, mutect2, varscan2
- RIMS1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 365/548 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs775577398, COSV53482094; called by muse, mutect2, varscan2
- RIMS1 | c.1568G>A p.G523D | Missense Mutation (SNP) | VAF 174/594 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs1265965301; called by muse, mutect2, varscan2
- RING1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 276/542 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.586); catalogued as rs543164083, COSV100761701; called by muse, mutect2, varscan2
- RNF213 | c.1079del p.N360Tfs*9 | Frame Shift Del (DEL) | VAF 161/402 reads (40%) | catalogued as rs775429031; called by mutect2, pindel, varscan2
- RNF5 | c.526del p.W176Gfs*22 | Frame Shift Del (DEL) | VAF 139/377 reads (37%) | catalogued as rs758165894; called by mutect2, pindel, varscan2
- RNPEP | c.1169A>C p.N390T | Missense Mutation (SNP) | VAF 164/355 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1192596527, COSV55241430; called by muse, mutect2
- ROCK1 | c.2612dup p.N871Kfs*14 | Frame Shift Ins (INS) | VAF 38/105 reads (36%) | catalogued as rs1336897725; called by mutect2, varscan2
- RP1 | c.4598C>T p.A1533V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99608890; called by muse, mutect2
- RP1L1 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 62/626 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs746269632, COSV101223220; called by muse, mutect2
- RPA4 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 186/411 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs745560952; called by muse, mutect2, varscan2
- RSBN1 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54732760; called by muse, mutect2, varscan2
- RSPO4 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs200584918, COSV99449584; called by muse, mutect2
- RYR1 | c.12916C>T p.R4306* | Nonsense Mutation (SNP) | VAF 107/177 reads (60%) | catalogued as rs1329745881; called by muse, mutect2, varscan2
- RYR1 | c.15059G>T p.W5020L | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM140871; called by muse, mutect2, varscan2
- SACS | c.2098C>A p.L700I | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV66542960; called by muse, mutect2
- SAMD14 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs764972672; called by muse, mutect2, varscan2
- SBF1 | c.4874C>T p.T1625M | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs756843805; called by muse, mutect2
- SBK3 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 268/545 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs771744445, COSV100705318; called by muse, mutect2, varscan2
- SBNO1 | c.4006C>T p.R1336W (on ENST00000420886; = p.R1335W on NM_018183.5) | Missense Mutation (SNP) | VAF 160/312 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV57339340; called by muse, mutect2, varscan2
- SBNO1 | c.1267C>T p.H423Y (on ENST00000420886; = p.H422Y on NM_018183.5) | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs781451041; called by muse, mutect2, varscan2
- SCAMP2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs142248311; called by muse, mutect2, varscan2
- SCFD1 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753170714, COSV61722253; called by muse, mutect2, varscan2
- SCML1 | c.530G>A p.R177H (on ENST00000380041 / NM_001037540.3; = p.R150H on NM_006746.6) | Missense Mutation (SNP) | VAF 34/613 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs371840167, COSV66240948; called by muse, mutect2
- SCN10A | c.4280del p.K1427Sfs*2 | Frame Shift Del (DEL) | VAF 76/163 reads (47%) | catalogued as rs750400627; called by mutect2, varscan2
- SCN8A | c.1790G>T p.R597L | Missense Mutation (SNP) | VAF 214/439 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV61978463; called by muse, mutect2, varscan2
- SCNN1D | c.53del p.G18Afs*179 (on ENST00000338555; = p.A151Lfs*18 on NM_001130413.4) | Frame Shift Del (DEL) | VAF 99/206 reads (48%) | catalogued as rs1270083658; called by mutect2, pindel, varscan2
- SCRN1 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV99621662; called by muse, mutect2, varscan2
- SCT | c.10dup p.R4Pfs*? | Frame Shift Ins (INS) | VAF 93/222 reads (42%) | catalogued as rs1042460219; called by mutect2, pindel, varscan2
- SDK1 | c.1721C>T p.T574M | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765996731; called by muse, mutect2, varscan2
- SEC63 | c.1586_1596delinsGAAACCTTT p.K529Rfs*4 | Frame Shift Del (DEL) | VAF 108/515 reads (21%) | catalogued as COSV64602454; called by pindel, varscan2*
- SELE | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 104/230 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.066); catalogued as rs764857890; called by muse, mutect2, varscan2
- SEMA4A | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 58/654 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.424); catalogued as rs779154677; ClinVar: uncertain significance; called by muse, mutect2
- SEPTIN12 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750686221, COSV99190712; called by muse, mutect2, varscan2
- SERBP1 | c.1091G>A p.R364H (on ENST00000370995 / NM_001018067.2; = p.R343H on NM_015640.4) | Missense Mutation (SNP) | VAF 139/287 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1236604886; called by muse, mutect2, varscan2
- SERBP1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.262); catalogued as rs763708277, COSV100769035; called by muse, varscan2
- SEZ6L | c.2481del p.T828Pfs*19 | Frame Shift Del (DEL) | VAF 175/466 reads (38%) | catalogued as COSV50668291, COSV50668348; called by mutect2, pindel, varscan2
- SGSM2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 140/285 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768701962, COSV99279801; called by muse, mutect2, varscan2
- SHC2 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 172/377 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs374025306; called by muse, mutect2, varscan2
- SIX5 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 30/778 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs1207525930; called by muse, mutect2
- SLC18A3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 309/607 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427981231; called by muse, mutect2, varscan2
- SLC26A6 | c.1618del p.V540* | Frame Shift Del (DEL) | VAF 116/263 reads (44%) | catalogued as rs780816364, COSV56576227; called by mutect2, pindel, varscan2
- SLC27A4 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 134/302 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs775550483; called by muse, varscan2
- SLC29A2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 117/253 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs962219949, COSV60802980; called by muse, mutect2, varscan2
- SLC40A1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as rs772246537, COSV53722881; called by muse, mutect2
- SLC48A1 | c.47G>A p.G16D | Missense Mutation (SNP) | VAF 222/511 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs1376789239; called by muse, mutect2, varscan2
- SLC4A1AP | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 97/193 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1354643142, COSV58134019; called by muse, mutect2, varscan2
- SLC52A3 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 224/430 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs890766612, CM150415; called by muse, mutect2
- SLC9A3 | c.366del p.I123Sfs*97 | Frame Shift Del (DEL) | VAF 276/697 reads (40%) | catalogued as COSV53805830; called by mutect2, pindel, varscan2
- SLC9A5 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 128/280 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs781377833; called by muse, mutect2, varscan2
- SLCO4A1 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 251/560 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs747381074; called by muse, mutect2, varscan2
- SLITRK5 | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 422/618 reads (68%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs138918593; called by muse, varscan2
- SMAD9 | c.1135G>A p.G379S (on ENST00000379826 / NM_001127217.3; = p.G342S on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 421/658 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as rs267603814; called by muse, mutect2, varscan2
- SMARCA2 | c.1916A>G p.D639G | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1313222350; called by muse, varscan2
- SMC2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 119/284 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs1393873596; called by muse, mutect2, varscan2
- SOAT2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 144/320 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753091495; called by muse, mutect2, varscan2
- SOCS1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 278/574 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs765480579, COSV104406545, COSV59659294; called by muse, mutect2, varscan2
- SORCS2 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 122/238 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs368456515; called by muse, mutect2, varscan2
- SOST | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 189/436 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs770637509; called by muse, varscan2
- SOX1 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 303/416 reads (73%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.153); catalogued as rs1397719706; called by muse, mutect2, varscan2
- SOX12 | c.749A>G p.E250G | Missense Mutation (SNP) | VAF 322/661 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100705315; called by muse, mutect2, varscan2
- SOX3 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 351/704 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65167886, COSV65167951, COSV65168349; called by muse, varscan2
- SOX5 | c.1777C>T p.R593C | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs761144841; called by muse, mutect2, varscan2
- SOX9 | c.66del p.S23Afs*38 | Frame Shift Del (DEL) | VAF 491/687 reads (71%) | catalogued as COSV55428538; called by mutect2, pindel, varscan2
- SPAG4 | c.1223del p.G408Afs*43 | Frame Shift Del (DEL) | VAF 182/436 reads (42%) | catalogued as rs1325769949; called by mutect2, pindel, varscan2
- SPEF2 | c.3942dup p.P1315Tfs*4 | Frame Shift Ins (INS) | VAF 64/197 reads (32%) | catalogued as rs1278479902; called by mutect2, pindel, varscan2
- SPHKAP | c.4220C>T p.S1407L | Missense Mutation (SNP) | VAF 130/272 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs774839623, COSV60895428; called by muse, mutect2, varscan2
- SPN | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs748002037; called by muse, mutect2, varscan2
- SPTB | c.6865G>A p.E2289K | Missense Mutation (SNP) | VAF 200/404 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs939852403; called by muse, mutect2, varscan2
- SPTBN1 | c.5987C>T p.T1996M | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs749969944; called by muse, mutect2, varscan2
- SPTBN5 | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 254/535 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs371369677; called by muse, mutect2, varscan2
- SRCIN1 | c.2648C>T p.T883M (on ENST00000621492; = p.T849M on NM_025248.3) | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs767903662; called by muse, mutect2, varscan2
- SRRM4 | c.79del p.R27Vfs*74 | Frame Shift Del (DEL) | VAF 237/550 reads (43%) | catalogued as COSV57409015; called by mutect2, pindel, varscan2
- SSR4 | c.364A>G p.N122D | Missense Mutation (SNP) | VAF 180/411 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs1557073150; called by muse, mutect2, varscan2
- STEAP2 | c.680del p.F227Sfs*9 | Frame Shift Del (DEL) | VAF 134/272 reads (49%) | catalogued as rs754344704; called by mutect2, varscan2
- STK10 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 154/321 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs751520134; called by muse, mutect2, varscan2
- STMN4 | c.257G>A p.R86Q (on ENST00000265770 / NM_001283054.2; = p.R113Q on NM_030795.4) | Missense Mutation (SNP) | VAF 155/338 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV99741248; called by muse, mutect2, varscan2
- STRC | c.733del p.A245Pfs*78 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs1329435668; called by mutect2, varscan2
- SURF4 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 32/433 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs909631149; called by muse, mutect2
- SUSD2 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 166/381 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs766634160, COSV64205249; called by muse, mutect2, varscan2
- SV2A | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 23/452 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs149927876, COSV64964911; called by muse, mutect2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 51/126 reads (40%) | catalogued as rs776683356; called by mutect2, varscan2
- SYCP2 | c.3948dup p.L1317Tfs*3 | Frame Shift Ins (INS) | VAF 92/239 reads (38%) | catalogued as rs755832373; called by mutect2, pindel, varscan2
- SZT2 | c.9379C>T p.R3127* (on ENST00000634258 / NM_001365999.1; = p.R3070* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 170/424 reads (40%) | catalogued as rs770264092; called by muse, mutect2, varscan2
- TAF3 | c.2155_2157del p.K719del | In Frame Del (DEL) | VAF 92/189 reads (49%) | catalogued as rs777381826; called by pindel, varscan2
- TANC1 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 155/316 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs111308152; called by muse, mutect2, varscan2
- TAS2R3 | c.532T>C p.Y178H | Missense Mutation (SNP) | VAF 156/354 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV56091766; called by muse, mutect2, varscan2
- TBC1D2 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374539701; called by muse, mutect2, varscan2
- TCAF1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs774779542; called by muse, mutect2, varscan2
- TCF20 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 202/422 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.846); catalogued as rs781181631; called by muse, mutect2, varscan2
- TCF7L2 | c.1696G>A p.A566T (on ENST00000355995 / NM_001367943.1; = p.A543T on NM_030756.5) | Missense Mutation (SNP) | VAF 303/666 reads (45%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.981); catalogued as rs1414332733, COSV53343553; called by muse, mutect2, varscan2
- TECTA | c.4168G>A p.A1390T | Missense Mutation (SNP) | VAF 173/367 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1481202790, COSV50723773, COSV50838420; ClinVar: uncertain significance; called by muse, varscan2
- TERT | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 34/664 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1304418053, COSV57245436; ClinVar: uncertain significance; called by muse, mutect2
- TEX13A | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 251/493 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs782161125, COSV61172549; called by muse, mutect2, varscan2
- TH | c.1451G>A p.R484H (on ENST00000381178 / NM_199292.3; = p.R453H on NM_000360.4) | Missense Mutation (SNP) | VAF 214/485 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759599321, CM149051, COSV51746427; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- THAP6 | c.473G>A p.C158Y | Missense Mutation (SNP) | VAF 120/273 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1411546351; called by muse, mutect2, varscan2
- THBS3 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 144/298 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1340791242, COSV64250783; called by muse, mutect2, varscan2
- THBS4 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 139/260 reads (53%) | catalogued as rs1400187389; called by muse, varscan2
- THSD7A | c.1373G>A p.G458D | Missense Mutation (SNP) | VAF 148/318 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101448597; called by muse, varscan2
- THTPA | c.80del p.G27Afs*19 | Frame Shift Del (DEL) | VAF 162/407 reads (40%) | catalogued as rs757375466; called by mutect2, pindel, varscan2
- TIAM1 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 176/350 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs375094556; called by muse, varscan2
- TIAM2 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 150/291 reads (52%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.819); catalogued as rs776715966, COSV59704076; called by muse, mutect2, varscan2
- TIE1 | c.1942del p.R648Dfs*15 | Frame Shift Del (DEL) | VAF 126/315 reads (40%) | catalogued as COSV65250259; called by mutect2, pindel, varscan2
- TINF2 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 134/260 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs749534744; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLCD2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 307/660 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as rs1206351761; called by muse, mutect2, varscan2
- TMA16 | c.200del p.K67Rfs*11 | Frame Shift Del (DEL) | VAF 20/231 reads (9%) | catalogued as rs768974165, COSV62187111; called by mutect2, pindel
- TMCO3 | c.1687A>G p.I563V | Missense Mutation (SNP) | VAF 230/356 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs766290613; called by muse, mutect2, varscan2
- TMEM101 | c.638del p.P213Lfs*25 | Frame Shift Del (DEL) | VAF 195/460 reads (42%) | catalogued as rs757377702, COSV52814337; called by mutect2, pindel, varscan2
- TMEM107 | c.311G>A p.R104H (on ENST00000437139 / NM_183065.4; = p.R110H on NM_032354.5) | Missense Mutation (SNP) | VAF 142/319 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.583); catalogued as rs1368021784; called by muse, mutect2, varscan2
- TMEM132D | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 230/547 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756920052, COSV70607867, COSV70623172; called by muse, varscan2
- TMEM72 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs751205286, COSV67460538; called by muse, mutect2, varscan2
- TMEM79 | c.677T>G p.V226G | Missense Mutation (SNP) | VAF 269/526 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55296582; called by muse, mutect2, varscan2
- TNFSF14 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 222/505 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs763144962, COSV55590110; called by muse, mutect2, varscan2
- TNS1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 249/539 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1354496737, COSV50690052; called by muse, mutect2, varscan2
- TOP1MT | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 145/310 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs764945190, COSV100239625, COSV61318887; called by muse, mutect2, varscan2
- TOPORS | c.1705T>C p.S569P | Missense Mutation (SNP) | VAF 97/252 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100859547; called by muse, mutect2, varscan2
- TPM2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 130/275 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61405465; called by muse, mutect2, varscan2
- TPR | c.6760A>G p.T2254A | Missense Mutation (SNP) | VAF 148/343 reads (43%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.003); catalogued as rs766953331; called by muse, mutect2, varscan2
- TRAF3IP3 | c.524T>G p.I175S | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.124); catalogued as COSV50558129; called by muse, mutect2, varscan2
- TRAM1L1 | c.394del p.S132Lfs*9 | Frame Shift Del (DEL) | VAF 96/226 reads (42%) | catalogued as rs757906221; called by mutect2, pindel, varscan2
- TRAV8-7 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as rs376612923; called by muse, mutect2
- TRIL | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 328/672 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV59868206; called by muse, varscan2
- TRIM16L | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 153/331 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs370288641; called by muse, mutect2, varscan2
- TRIM24 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.32); catalogued as rs772873132, COSV58970567; called by muse, mutect2, varscan2
- TRIM25 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 176/345 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1412528868; called by muse, mutect2, varscan2
- TRIM26 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 342/663 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.223); catalogued as rs780620559, COSV68963571; called by muse, mutect2, varscan2
- TRIM49 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 114/300 reads (38%) | catalogued as COSV61670731; called by muse, mutect2, varscan2
- TRIM55 | c.860del p.I288Sfs*13 | Frame Shift Del (DEL) | VAF 78/219 reads (36%) | catalogued as rs1354534266; called by mutect2, pindel, varscan2
- TRIM65 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 236/503 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as rs369294498, COSV99485623; called by muse, mutect2, varscan2
- TRIM66 | c.247C>A p.L83I | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV101238440; called by muse, mutect2
- TRIO | c.5066C>T p.P1689L | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs759701866; called by muse, varscan2
- TRIOBP | c.3536G>A p.R1179H | Missense Mutation (SNP) | VAF 263/553 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs771635907, COSV60375876; called by muse, mutect2, varscan2
- TRMT5 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 131/285 reads (46%) | catalogued as rs867767714, COSV50781646; called by muse, mutect2, varscan2
- TRPC4 | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 275/426 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV59006610, COSV59012215; called by muse, mutect2, varscan2
- TRPC6 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1419102467, COSV60251572; called by muse, mutect2, varscan2
- TRPM2 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as rs559123321; called by muse, mutect2, varscan2
- TRPS1 | c.2608T>C p.Y870H (on ENST00000220888 / NM_001330599.2; = p.Y883H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/335 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as COSV55227677; called by muse, mutect2, varscan2
- TSHZ3 | c.2336G>A p.R779H | Missense Mutation (SNP) | VAF 185/383 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as rs546107129, COSV99552029; called by muse, mutect2, varscan2
- TSHZ3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 223/424 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs768951623, COSV53665675; called by muse, mutect2, varscan2
- TSPAN11 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 242/529 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs753944071, COSV53818740; called by muse, mutect2
- TSPAN32 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 134/270 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1294110439; called by muse, varscan2
- TTC25 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs561600194; called by muse, mutect2, varscan2
- TTN | c.94057G>T p.D31353Y (on ENST00000591111; = p.D23929Y on NM_003319.4) | Missense Mutation (SNP) | VAF 50/145 reads (34%) | PolyPhen probably damaging (0.999); catalogued as COSV99045779; called by muse, mutect2, varscan2
- TTN | c.88801C>T p.R29601C (on ENST00000591111; = p.R22177C on NM_003319.4) | Missense Mutation (SNP) | VAF 165/338 reads (49%) | PolyPhen probably damaging (0.998); catalogued as rs563887822, COSV60215066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.65090G>A p.R21697Q (on ENST00000591111; = p.R14273Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/288 reads (7%) | PolyPhen benign (0.011); catalogued as rs78916558, COSV60338352; ClinVar: uncertain significance; called by muse, mutect2
- UBE2D4 | c.304+8T>C | Splice Region (SNP) | VAF 28/524 reads (5%) | catalogued as rs1457504787; called by muse, mutect2
- UBE2G1 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1293550747, COSV67835217; called by muse, mutect2, varscan2
- UBE2O | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 155/322 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs759134620; called by muse, mutect2, varscan2
- UBR4 | c.9674G>A p.R3225H | Missense Mutation (SNP) | VAF 150/294 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs769718135, COSV64382776; called by muse, varscan2
- UCP1 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs775118020, CM973745; called by muse, mutect2, varscan2
- UCP3 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 190/424 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs183714776, COSV100012903; called by muse, mutect2, varscan2
- UFD1 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1244215037, COSV54244825; called by muse, mutect2
- USP28 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 125/218 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs780410860, COSV50156636; called by muse, mutect2, varscan2
- USP3 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV51429445; called by muse, mutect2, varscan2
- USP31 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 150/347 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54851159; called by muse, mutect2, varscan2
- USP35 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs770791883, COSV71572731; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 171/406 reads (42%) | catalogued as rs764735138; called by mutect2, varscan2
- USP42 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 252/498 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1404461529; called by muse, mutect2, varscan2
- VAV3 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 109/271 reads (40%) | catalogued as rs1252178608; called by muse, mutect2, varscan2
- VILL | c.1927A>G p.M643V | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs762218324, COSV52182209; called by muse, mutect2, varscan2
- VLDLR | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1353643357, COSV66074234; called by muse, mutect2, varscan2
- VN1R4 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746243960; called by mutect2, varscan2
- VPS13B | c.4232G>A p.R1411H | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.745); catalogued as COSV62132609; called by muse, mutect2, varscan2
- VPS39 | c.1850G>A p.R617Q (on ENST00000348544 / NM_001301138.2; = p.R606Q on NM_015289.5) | Missense Mutation (SNP) | VAF 134/307 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs142437559; called by muse, mutect2, varscan2
- VWA5B2 | c.731dup p.H245Sfs*19 | Frame Shift Ins (INS) | VAF 124/303 reads (41%) | catalogued as rs770124856; called by mutect2, varscan2
- WASHC5 | c.2273T>C p.I758T | Missense Mutation (SNP) | VAF 177/333 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs184833599; called by muse, mutect2, varscan2
- WASL | c.1263del p.V422Wfs*17 | Frame Shift Del (DEL) | VAF 118/347 reads (34%) | catalogued as rs1158703313; called by pindel, varscan2
- WDR11 | c.40A>G p.T14A | Missense Mutation (SNP) | VAF 207/416 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV54789979; called by muse, mutect2, varscan2
- WDR59 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 116/259 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as rs376086980, COSV50941829; called by muse, mutect2, varscan2
- WDR97 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 260/591 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1273881786; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 80/170 reads (47%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WWOX | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 204/408 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs765339835, COSV68355437; called by muse, varscan2
- XDH | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 206/445 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs202023189, COSV65148059; called by muse, mutect2, varscan2
- YEATS2 | c.3757del p.V1253Cfs*2 | Frame Shift Del (DEL) | VAF 134/338 reads (40%) | catalogued as COSV59361709; called by mutect2, pindel, varscan2
- YJEFN3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 174/402 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs866284060; called by muse, mutect2, varscan2
- YTHDC2 | c.1316A>G p.Y439C | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.659); catalogued as rs1332184987; called by muse, mutect2, varscan2
- ZBTB2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 126/278 reads (45%) | catalogued as COSV57311689, COSV57311951; called by muse, mutect2, varscan2
- ZBTB20 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.528); catalogued as rs1276357389; called by muse, mutect2
- ZC3H4 | c.2002G>A p.G668S | Missense Mutation (SNP) | VAF 216/488 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.584); catalogued as COSV53410706; called by muse, mutect2, varscan2
- ZC3H6 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs527649083; called by muse, mutect2, varscan2
- ZC3H6 | c.2903del p.N968Ifs*19 | Frame Shift Del (DEL) | VAF 118/218 reads (54%) | catalogued as rs1340538397; called by mutect2, varscan2
- ZDBF2 | c.3764G>A p.G1255D | Missense Mutation (SNP) | VAF 145/302 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as rs868207669; called by muse, mutect2, varscan2
- ZDHHC3 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 115/235 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs750368996, COSV56102007; called by muse, mutect2, varscan2
- ZEB2 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1217004857; called by muse, mutect2, varscan2
- ZFYVE1 | c.904T>C p.C302R | Missense Mutation (SNP) | VAF 131/269 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs775752685; called by muse, varscan2
- ZNF155 | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386367707; called by muse, mutect2, varscan2
- ZNF202 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1281228234; called by muse, mutect2, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 106/272 reads (39%) | catalogued as rs774038489; called by mutect2, pindel, varscan2
- ZNF263 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV54596946; called by muse, varscan2
- ZNF292 | c.3455A>G p.K1152R | Missense Mutation (SNP) | VAF 305/458 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs769058799; called by muse, mutect2, varscan2
- ZNF318 | c.3164C>T p.T1055I | Missense Mutation (SNP) | VAF 162/345 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs372785018; called by muse, mutect2, varscan2
- ZNF496 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 223/488 reads (46%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.877); catalogued as rs747132338; called by muse, mutect2, varscan2
- ZNF512B | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 276/595 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs946248668; called by muse, mutect2, varscan2
- ZNF541 | c.692del p.P231Rfs*49 | Frame Shift Del (DEL) | VAF 170/431 reads (39%) | catalogued as rs780386192; called by mutect2, pindel, varscan2
- ZNF556 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 203/428 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771188730, COSV100298814; called by muse, mutect2, varscan2
- ZNF608 | c.2534C>T p.A845V | Missense Mutation (SNP) | VAF 200/437 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as COSV60435863; called by muse, mutect2, varscan2
- ZNF608 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 192/373 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV100101206; called by muse, mutect2, varscan2
- ZNF672 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 56/866 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.109); catalogued as rs576771167; called by muse, mutect2
- ZNF716 | c.381del p.K127Nfs*6 | Frame Shift Del (DEL) | VAF 46/160 reads (29%) | catalogued as rs781946785; called by pindel, varscan2
- ZNF724 | c.345del p.G116Afs*22 | Frame Shift Del (DEL) | VAF 43/212 reads (20%) | catalogued as rs781412139; called by mutect2, pindel, varscan2
- ZNF76 | c.872A>G p.H291R | Missense Mutation (SNP) | VAF 259/500 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as rs756463580; called by muse, mutect2, varscan2
- ZNF830 | c.753del p.F251Lfs*6 | Frame Shift Del (DEL) | VAF 152/373 reads (41%) | catalogued as rs749765261; called by mutect2, pindel, varscan2
- ZNF831 | c.153del p.T52Lfs*4 | Frame Shift Del (DEL) | VAF 252/492 reads (51%) | catalogued as rs750329558; called by mutect2, varscan2
- ZNF835 | c.1399G>A p.V467M | Missense Mutation (SNP) | VAF 208/453 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV73379294; called by muse, mutect2, varscan2
- ZNF865 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 102/538 reads (19%) | SIFT tolerated (0.22); catalogued as rs1188216751; called by muse, mutect2, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 121/318 reads (38%) | catalogued as rs759348115; called by mutect2, pindel, varscan2
- ZNF90 | c.183del p.K61Nfs*5 | Frame Shift Del (DEL) | VAF 57/132 reads (43%) | catalogued as rs782512219; called by mutect2, pindel, varscan2
- ZP1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 118/297 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as rs763812579, COSV53923345, COSV53925243; called by muse, mutect2, varscan2
- ZSCAN9 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 137/272 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs762408614, COSV52851195; called by muse, mutect2, varscan2
- AATK | c.640C>A p.L214M (on ENST00000326724 / NM_001080395.3; = p.L111M on NM_004920.2) | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- ABCA5 | c.3975del p.G1326Efs*4 | Frame Shift Del (DEL) | VAF 63/147 reads (43%) | called by mutect2, pindel, varscan2
- ABCA7 | c.4934G>A p.S1645N | Missense Mutation (SNP) | VAF 182/405 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCA9 | c.3644T>G p.I1215S | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ABCB8 | c.1417A>G p.T473A (on ENST00000297504 / NM_001282291.2; = p.T456A on NM_007188.5) | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABCC3 | c.3283_3285del p.F1095del | In Frame Del (DEL) | VAF 156/355 reads (44%) | called by pindel, varscan2
- ABTB1 | c.1088del p.G363Afs*2 (on ENST00000232744 / NM_172027.3; = p.G221Afs*2 on NM_032548.3) | Frame Shift Del (DEL) | VAF 181/451 reads (40%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 173/359 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- AC109583.1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 211/449 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ACACB | c.1493C>A p.A498D | Missense Mutation (SNP) | VAF 154/345 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ACOX2 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 95/171 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTG2 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTN1 | c.1874A>G p.Q625R | Missense Mutation (SNP) | VAF 187/399 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ADAM17 | c.1871dup p.L624Ffs*13 | Frame Shift Ins (INS) | VAF 96/230 reads (42%) | called by mutect2, pindel, varscan2
- ADAM20 | c.231G>T p.R77S | Missense Mutation (SNP) | VAF 34/307 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by mutect2, varscan2
- ADAM28 | c.1161del p.F387Lfs*63 | Frame Shift Del (DEL) | VAF 108/281 reads (38%) | called by mutect2, pindel, varscan2
1,226 further variants in this file (716 protein-altering or splice-affecting, 439 silent, 71 other) are not listed here.
